Surgical pathology report (de-identified scan), TCGA case TCGA-18-3412, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3412-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lung: Station 11L
2. Lymph node: Lobar ST12
3. Lungs: Left lower lobe - bronchial resection margin
4. Lungs: Completion left pneumonectomy - bronchial resection margin
5. Lymph node: Aorto-pulmonary ST5

DIAGNOSIS

- 1., 2. Interlobar ST11, lobar ST12:
- Negative for malignancy, lymph node.
3. Left lower lobe lung lobectomy:
- Squamous cell carcinoma, moderately differentiated, central.
- Tumor greatest diameter 4.7 cm.
- At the hilum, tumor has invaded into peribronchial fatty tissue.
- 2 lobar peribronchial lymph nodes negative for tumor.
- Bronchial resection margin positive for tumor involvement.
4. Left completion pneumonectomy:
- Microscopic residual squamous cell carcinoma noted in hilar area.
- All 4 lobar and 3 segmental peribronchial lymph nodes negative for tumor.
- One focus of effete granuloma involving pleural lymph node.
- Focal pleural and parenchymal fibrosis.
- Remaining lung parenchyma unremarkable.
- Bronchial resection margin negative for tumor.
5. Aorto-pulmonary ST5:
- Negative for malignancy, lymph node.

COMMENT

conjunction with the negative mediastinal lymph node biopsy results
[REDACTED], this tumor is staged as a pT2N0 cancer.

[page 2 of 4]
CLINICAL HISTORY
CANCER OF LEFT LUNG

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "interlobar ST11", contains two pieces of gray-black nodal tissue measuring 1.0 x 0.4 x 0.2 cm and 1.8 x 0.8 x 0.4 cm. received in 10% buffered formalin. The larger piece is bisected.
1A - submitted in toto.
2. The specimen container labeled with the patient's name and as "lobar ST12", contains a large black lymph node measuring 1.0 x 0.8 x 0.4 cm. received in 10% buffered formalin.
2A - bisected and submitted in toto.
3. The specimen container labeled with the patient's name and as "left lower lobe - bronchial resection margin", contains a lobe of lung that measures 15.5 x 14.0 x 5.7 cm in formalin-inflated state. The pleura is intact, mostly smooth and partly hemorrhagic. On the medial aspect adjacent to the bronchus there is ragged soft tissue adhered. On the medial anterior aspect extending from the apex to the inferior aspect there is a staple line margin measuring 14.0 cm long. The bronchial resection margin is examined at intraoperative consultation by frozen section. On sectioning the lung, there is a central tumor mass present measuring 4.7 cm in maximum diameter. The mass is solid tan-white with some gray-black query segmental lymph nodes admixed. Grossly the tumor appears to extend beyond the pleura and into the overlying ragged area of soft tissue which is adjacent to the bronchus. In this area the soft tissue is painted with silver nitrate. The tumor invades into the lobar bronchus and into the segmental bronchi. The tumor is also 2.0 cm away from the staple line resection margin. The rest of the lung parenchyma ranges from unremarkable to mildly emphysematous with more prominence at the apex. Four pieces of tumor and four pieces of grossly normal lung parenchyma are taken for tissue banking.
A - bronchial resection margin, frozen section resubmitted
3B-3D - tumor with overlying ragged soft tissue

[page 3 of 4]
3E, 3F - tumor with invasion into lumen of bronchus and ?segmental lymph nodes admixed

3G, 3H - grossly normal lung parenchyma away from tumor

3I - shaved staple line resection margin closest to tumor

3J - one possible lobar lymph node measuring 0.7 cm.

4. The specimen container labeled with the patient's name and as "completion left pneumonectomy bronchial resection margin", contains a lobe of lung received in 10% buffered formalin. It measures 17.5 x 13.0 x 4.5 cm in its formalin-inflated state. The pleura is intact, smooth and shiny. The main stem bronchus is cut long measuring ~ 3.0 cm and is cent and unremarkable. Along the medial aspect adjacent to the bronchus there is a staple line which measures 16.0 cm long from the apex to inferior aspect. Several black lobar and interlobar lymph nodes are identified, the largest 0.8 cm in diameter. On sectioning the lung, no lesions are identified. The parenchyma is mostly normal appearing with very mild emphysematous changes present at the periphery. Several black segmental lymph nodes are identified. The bronchial resection margin is examined at intraoperative consultation by frozen section.

4A - bronchial resection margin, frozen section resubmitted

4B - three lobar lymph nodes

4C - one lobar lymph node bisected

4D - ?one interlobar lymph node

4E - three segmental lymph nodes

4F - ?one bisected subsegmental lymph node or peripheral nodule measuring 0.8 cm in diameter

4G - thickened firm area of vessel

4H-4J - lung parenchyma.

4K left lower lobe bronchial resection margin at main stem bronchus

4L, 4M main stem bronchus serially sectioned transversely

4N vascular resection margin

5. The specimen container labeled with the patient's name and as "aorto-pulmonary ST5", contains two pieces of gray-black nodal tissue measuring 0.3 x 0.3 x 0.3 cm and 0.9 x 0.8 x 0.4 cm. received in 10% buffered formalin. The larger is bisected.

5A - submitted in toto.

1A "POSSIBLE FOR SQUAMOUS CELL CA"

Source: NCI Genomic Data Commons file 58fff7b5-d3ef-4f56-b051-3120ad639b76 (TCGA-18-3412.CAE58929-ECC1-4C4A-8DF6-CF48A32785EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).